Somatic mutation profile of tumor specimen 0DWQ44 from CCDI case PBCMLL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Desmoplastic nodular medulloblastoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 4.2 years (1,550 days).
Specimen 0DWQ44: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b17816ef-1270-4530-b667-00eefbe4e54a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWQ3U (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af0c2220-e389-4a00-a8bf-6e5037c2171d

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.1592C>T p.T531M (on ENST00000399959; = p.T532M on NM_001356.5) | Missense Mutation (SNP) | VAF 528/554 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064795387, COSV67863875; ClinVar: pathogenic; called by muse, varscan2
- ALDH16A1 | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 68/615 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866300390; called by muse, varscan2
- HMSD | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 118/1005 reads (12%) | catalogued as rs761923017, COSV68816811; called by muse, varscan2
- PNLIPRP3 | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 445/1228 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as COSV65049006; called by muse, varscan2
- IRS1 | c.2575A>C p.T859P | Missense Mutation (SNP) | VAF 335/711 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, varscan2
- BMP2K | c.1614G>A p.P538= | Silent (SNP) | VAF 96/541 reads (18%) | catalogued as rs767986751; called by muse, varscan2
- KALRN | c.6396C>T p.I2132= (on ENST00000360013 / NM_001024660.4; = p.I435= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 210/1067 reads (20%) | catalogued as rs190316626, COSV52260673; called by muse, varscan2
- LEFTY2 | c.816G>T p.L272= | Silent (SNP) | VAF 422/1246 reads (34%) | catalogued as rs762837520; called by muse, varscan2
